Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UV, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UV-01A (Primary Tumor).

[page 1 of 3]
	4/30/12	

id & Neck
id And Neck

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Pre- BCell lymph, now with left thyroid nodule showing FNA PTC

Specimens Submitted:

- 1: SP: Delphian node; excision (fs)
- 2: SP: Thyroid; total thyroidectomy

DIAGNOSIS:

1. Delphian node; excision:
-One benign lymph node

2. SP: Thyroid; total thyroidectomy.

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 1.0 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Focal Invasion

One focus of vascular invasion is noted

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Not identified

Non-Neoplastic Thyroid:

ICD-O-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9 5.2/2
20

[page 2 of 3]
Exhibits nodular hyperplasia
Parathyroid Glands:
Not Identified

Lymph Nodes:
One benign lymph node (0/1)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section consultation labeled "delphian node" and contains a piece of soft tissue measuring 0.4 x 0.3 x 0.3 cm. The specimen is submitted entirely.

Summary of sections:
FSC - frozen section control

2). The specimen is received fresh, labeled "total thyroidectomy" and consists of a thyroid weighing 14.5 g. The right lobe measures 3.9 x 1.8 x 1.2 cm, the left lobe measures 4.1 x 1.9 x 1.3 cm and the isthmus measures 2.2 x 0.8 x 0.4 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a poorly circumscribed, white, fibrous nodule that measures 0.8 x 0.6 by 0.6 cm. The remaining thyroid parenchyma is red tan and beefy. Representative sections of the specimen are submitted and a photograph has been taken. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:
N - nodule
LL - left lobe
IS - isthmus
RL - right lobe

Summary of Sections:

Part 1: SP: Delphian node; excision (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: SP: Thyroid; total thyroidectomy

Block	Sect. Site	PCs
1	IS	2
3	LL	4
2	N	2
3	RL	4

Intraoperative Consultation:

[page 3 of 3]
SP: Delphian node (fs): Benign lymph node (

Permanent: Same

Source: NCI Genomic Data Commons file 1d39e655-afed-4729-a47f-02ba897f2986 (TCGA-DJ-A3UV.1262D473-47E4-41EC-AA58-93D0E16CC678.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).